Surgical pathology report (de-identified scan), TCGA case TCGA-DU-6392, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Henry Ford Hospital, specimen TCGA-DU-6392-01A (Primary Tumor).

TCGA-DU-6392

PATH. NO:

NAME:

MED. REC. NO:

AGE/SEX:

DOB:

COLLECT DATE

PATHOLOGICAL DIAGNOSIS:

A. RIGHT PARIETAL BIOPSY:

1. ~~ANAPLASTIC~~ ASTROCYTOMA.

2. KI 67: 1-2%.

(MIB-1: 10-15%)

B. RIGHT PARIETAL BIOPSY: TRANSITIONAL ZONE OF THE INFILTRATING
ASTROCYTOMA.

Operation/Specimen: Rt. parietal tumor

Clinical History and Pre-Op Dx: Rt. parietal tumor.

GROSS PATHOLOGY: The specimen (A) labeled "right parietal tumor", is a portion of loose, gray-white to pink-white soft tissue, 1 cm. in diameter. A portion of the specimen has been examined by frozen section and is submitted and the remaining tissue in cassette 2.

Specimen B labeled "adjacent white matter", submitted in cassette 3.

Specimen C labeled "post infiltrating white matter", submitted in cassette 4.

INTRAOPERATIVE CONSULTATION, Frozen section diagnosis: Glioma.

MICROSCOPIC: Specimen A shows an astrocytoma with a loose, fibrillary background. The tumor is relatively hypercellular, with majority of cells being small astrocytes containing hyperchromatic nuclei. The tumor cells tend to group together, or form multinucleation. Gemistocytic form is also present. Occasional mitotic figures are seen. Vascular proliferation and endothelial hyperplasia is present. Tumor necrosis is not identified. GFAP stain confirms the astrocytic nature of the tumor cells. Ki67 is about 1-2%, MIB-1 is about 10-15%.

Specimens B and C show the transitional zone between relatively uninvolved parenchyma (cortex and white) and involved cortex and white matter which are infiltrated by neoplastic cells with large irregular, often naked nuclei. The cellularity and nuclear pleomorphism of the specimens B and C is less than the specimen A.

Source: NCI Genomic Data Commons file d753d246-e725-4321-b702-310847ab5724 (TCGA-DU-6392.EBD2FE7E-1D87-4831-B605-B6837C3DA443.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).